Gene-level copy-number profile of tumor specimen TCGA-AB-2839-03A from TCGA case TCGA-AB-2839, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.9 years (18,963 days).
Specimen TCGA-AB-2839-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.38db73c1-5b69-47d0-9c4c-4b64395773d2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2839-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/a4533820-234c-45eb-ad5f-5c671b83395e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 48; copy number 2: 59,772.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 48. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
